Somatic mutation profile of tumor specimen TCGA-IB-A5SP-01A (aliquot TCGA-IB-A5SP-01A-11D-A32N-08) from TCGA case TCGA-IB-A5SP, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 77.5 years (28,317 days).
Specimen TCGA-IB-A5SP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78f67c6a-cf80-44f7-a2a8-d669110bbc8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-A5SP-10A (Blood Derived Normal), aliquot TCGA-IB-A5SP-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb49bf96-925f-41fa-9fce-a1f08704c41a

The open-access MAF lists 50 somatic variants for this specimen: 36 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 28, Silent 14, Frame Shift Ins 3, Frame Shift Del 3, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AXIN2 | c.1994dup p.N666Qfs*41 | Frame Shift Ins (INS) | VAF 106/208 reads (51%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 56/97 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 127/249 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS19 | c.1901G>A p.R634K | Missense Mutation (SNP) | VAF 268/728 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV99179819; called by muse, mutect2, varscan2
- C4orf17 | c.800T>C p.V267A | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV100431058; called by muse, mutect2
- CACNA1C | c.3224C>T p.T1075M | Missense Mutation (SNP) | VAF 69/142 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as rs766410481, COSV59763546; called by muse, mutect2, varscan2
- COL23A1 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 162/422 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101179490; called by muse, mutect2, varscan2
- ERCC4 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 39/82 reads (48%) | catalogued as COSV100319041, COSV61312578; called by muse, mutect2, varscan2
- ERCC6L2 | c.949T>A p.W317R | Missense Mutation (SNP) | VAF 91/237 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99998891; called by muse, mutect2, varscan2
- GATA3 | c.690C>A p.S230R | Missense Mutation (SNP) | VAF 88/466 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.296); catalogued as COSV100651150; called by muse, varscan2
- GK2 | c.707C>G p.S236C | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.14); catalogued as COSV100726015, COSV62626400, COSV62628410; called by muse, mutect2
- GRM1 | c.3073C>G p.P1025A | Missense Mutation (SNP) | VAF 127/497 reads (26%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV99268178; called by muse, mutect2, varscan2
- H2AC6 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 26/297 reads (9%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); catalogued as COSV100020020; called by muse, mutect2
- KDM5B | c.3634G>T p.G1212C | Missense Mutation (SNP) | VAF 134/279 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV99351147; called by muse, mutect2, varscan2
- KIF26A | c.3641C>T p.P1214L | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs747471698, COSV100180837, COSV100181321; called by muse, mutect2, varscan2
- MGAT5 | c.79A>G p.M27V | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.879); catalogued as COSV99924849; called by muse, mutect2, varscan2
- MUC16 | c.30306G>T p.M10102I | Missense Mutation (SNP) | VAF 136/431 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1422932717, COSV67482326; called by muse, mutect2, varscan2
- MYO15A | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1263068319, COSV52765044; called by muse, mutect2, varscan2
- ONECUT2 | c.596G>C p.R199P | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV101529807; called by muse, varscan2
- P4HA1 | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 270/698 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99697089; called by muse, mutect2, varscan2
- PCDH15 | c.1729C>T p.R577W | Missense Mutation (SNP) | VAF 162/408 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1374138920, COSV57313505; called by muse, mutect2, varscan2
- PLD5 | c.1387C>G p.Q463E (on ENST00000442594; = p.Q401E on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 131/442 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.119); catalogued as COSV100141985; called by muse, mutect2, varscan2
- SCAF11 | c.662G>A p.S221N | Missense Mutation (SNP) | VAF 86/257 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV101014563; called by muse, mutect2, varscan2
- SLC19A1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT tolerated (0.5); PolyPhen benign (0.031); catalogued as rs750614412, COSV100229555; called by muse, mutect2, varscan2
- SPATA31D1 | c.2704A>T p.M902L | Missense Mutation (SNP) | VAF 88/258 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV100782967; called by muse, mutect2, varscan2
- TLN2 | c.3968C>T p.S1323F | Missense Mutation (SNP) | VAF 68/286 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV100169727; called by muse, mutect2, varscan2
- TOX2 | c.1070G>A p.R357Q (on ENST00000358131 / NM_001098798.2; = p.R333Q on NM_032883.3) | Missense Mutation (SNP) | VAF 202/564 reads (36%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.978); catalogued as rs773686339, COSV57882392; called by muse, mutect2, varscan2
- TPTE | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 221/942 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs759630343; called by muse, mutect2, varscan2
- TTN | c.69650T>A p.I23217N (on ENST00000591111; = p.I15793N on NM_003319.4) | Missense Mutation (SNP) | VAF 58/179 reads (32%) | PolyPhen possibly damaging (0.735); catalogued as COSV100623548; called by muse, mutect2, varscan2
- ZNF441 | c.1264A>G p.K422E | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.182); catalogued as COSV100777449; called by muse, mutect2, varscan2
- GNPDA2 | c.105dup p.T36Yfs*15 | Frame Shift Ins (INS) | VAF 94/211 reads (45%) | called by mutect2, pindel, varscan2
- KDM6A | c.619+4_619+7del p.X207_splice | Splice Site (DEL) | VAF 102/170 reads (60%) | called by pindel, varscan2
- MECOM | c.1334_1340del p.N445Rfs*14 (on ENST00000468789 / NM_001105078.4; = p.N633Rfs*14 on NM_004991.4) | Frame Shift Del (DEL) | VAF 104/301 reads (35%) | called by mutect2, pindel, varscan2
- RREB1 | c.2238del p.D746Efs*167 | Frame Shift Del (DEL) | VAF 130/283 reads (46%) | called by mutect2, pindel, varscan2
- SCN7A | c.1130dup p.S378Kfs*21 | Frame Shift Ins (INS) | VAF 42/128 reads (33%) | called by mutect2, varscan2
- SMAD4 | c.1585_1588del p.L529Tfs*7 | Frame Shift Del (DEL) | VAF 172/337 reads (51%) | called by mutect2, pindel, varscan2
- ASB18 | c.1227G>A p.P409= | Silent (SNP) | VAF 62/176 reads (35%) | catalogued as rs201896139; called by muse, mutect2, varscan2
- CCDC92 | c.21G>A p.S7= | Silent (SNP) | VAF 128/360 reads (36%) | catalogued as rs148809811, COSV53019361; called by muse, mutect2, varscan2
- DDIAS | c.2637A>C p.G879= | Silent (SNP) | VAF 42/352 reads (12%) | catalogued as COSV100231366; called by muse, mutect2, varscan2
- FAM47A | c.222C>T p.D74= | Silent (SNP) | VAF 257/368 reads (70%) | catalogued as COSV60495771; called by muse, mutect2, varscan2
- GCNT1 | c.783C>T p.V261= | Silent (SNP) | VAF 131/446 reads (29%) | catalogued as COSV65057259; called by muse, mutect2, varscan2
- MAP3K6 | c.1863G>A p.T621= | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as COSV100709111, COSV100709382; called by muse, mutect2, varscan2
- MRGPRX2 | c.186C>T p.N62= | Silent (SNP) | VAF 92/682 reads (13%) | catalogued as rs974534357, COSV100316805; called by muse, mutect2, varscan2
- PCDHA1 | c.714C>T p.N238= | Silent (SNP) | VAF 182/477 reads (38%) | catalogued as rs782103349, COSV65373257; called by muse, mutect2, varscan2
- PPIP5K1 | c.3717C>T p.S1239= (on ENST00000396923; = p.S1214= on NM_014659.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 246/660 reads (37%) | catalogued as rs1253121792, COSV100289039; called by muse, mutect2, varscan2
- RASA3 | c.1686G>A p.S562= | Silent (SNP) | VAF 93/242 reads (38%) | catalogued as rs557790275, COSV61865875; called by muse, mutect2, varscan2
- TMEM117 | c.1452C>T p.T484= | Silent (SNP) | VAF 281/760 reads (37%) | catalogued as rs759645583, COSV99863328; called by muse, mutect2, varscan2
- TSHZ2 | c.1860C>T p.H620= | Silent (SNP) | VAF 198/600 reads (33%) | catalogued as rs143642849, COSV61590811; called by muse, mutect2, varscan2
- USH2A | c.11142A>G p.Q3714= | Silent (SNP) | VAF 115/444 reads (26%) | catalogued as rs1488110538, COSV56358857; called by muse, mutect2, varscan2
- YY1AP1 | c.774G>A p.K258= (on ENST00000295566 / NM_139118.2; = p.K181= on NM_018253.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/201 reads (23%) | catalogued as COSV99804476; called by muse, mutect2, varscan2
